Somatic mutation profile of tumor specimen C3N-03439-02 (aliquot CPT0246260010) from CPTAC case C3N-03439, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 56.9 years (20,776 days).
Specimen C3N-03439-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8f3b13f1-049f-4373-9b50-d898027ecd88.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03439-31 (Blood Derived Normal), aliquot CPT0246300002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/51d28902-b0d7-4fac-8c92-6406d225d045

The open-access MAF lists 85 somatic variants for this specimen: 53 protein-altering or splice-affecting, 13 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 13, RNA 5, Intron 5, 5'UTR 4, 3'Flank 4, Nonsense Mutation 2, Splice Site 1, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 46/504 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 51/482 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AMIGO2 | c.1136C>T p.T379I | Missense Mutation (SNP) | VAF 19/290 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.062); catalogued as COSV99873491; called by muse, mutect2
- ASB18 | c.1216A>G p.M406V | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs757623786; called by muse, varscan2
- ATP13A2 | c.2236G>T p.A746S | Missense Mutation (SNP) | VAF 62/626 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as CM085956; called by muse, mutect2
- AVPR2 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 32/347 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs782715616, COSV61686551; called by muse, mutect2
- CFTR | c.2629T>G p.S877A | Missense Mutation (SNP) | VAF 211/855 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0.305); catalogued as rs761531223; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTNAP5 | c.1514C>A p.P505H | Missense Mutation (SNP) | VAF 9/244 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV70477200; called by muse, mutect2
- COL5A1 | c.577C>T p.R193C | Missense Mutation (SNP) | VAF 74/780 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs765170704, COSV65667693; called by muse, mutect2
- EZHIP | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 50/457 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as COSV57957185; called by muse, mutect2, varscan2
- FGF14 | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 85/1001 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs868433062, COSV65951449; called by muse, mutect2
- FRMD7 | c.1492del p.Y498Mfs*26 | Frame Shift Del (DEL) | VAF 36/401 reads (9%) | catalogued as CD087853, CD118788; called by mutect2, pindel
- GABRQ | c.852G>T p.W284C | Missense Mutation (SNP) | VAF 26/346 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64784053; called by muse, mutect2
- GRHL1 | c.1847C>T p.T616M | Missense Mutation (SNP) | VAF 14/161 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.313); catalogued as rs143356570; called by muse, mutect2
- NRROS | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 45/392 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as rs572343955, COSV60746064; called by muse, mutect2, varscan2
- NRXN1 | c.4081G>A p.D1361N | Missense Mutation (SNP) | VAF 60/666 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV60526410; called by muse, mutect2
- NTAN1 | c.283G>A p.G95R | Missense Mutation (SNP) | VAF 28/376 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs753802699; called by muse, mutect2
- OLFML2B | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs759621817, COSV54195956; called by muse, mutect2
- OR10S1 | c.503C>T p.T168M | Missense Mutation (SNP) | VAF 54/428 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs777181185, COSV73343037; called by muse, mutect2, varscan2
- OR4D11 | c.278C>A p.S93Y | Missense Mutation (SNP) | VAF 27/334 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs371625986; called by muse, mutect2
- POM121L12 | c.214G>A p.V72M | Missense Mutation (SNP) | VAF 32/440 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.371); catalogued as COSV68692387; called by muse, mutect2
- RAB39B | c.463C>T p.R155* | Nonsense Mutation (SNP) | VAF 37/233 reads (16%) | catalogued as COSV101034956, COSV65624331; called by muse, mutect2, varscan2
- RYR2 | c.4444C>T p.R1482C | Missense Mutation (SNP) | VAF 36/496 reads (7%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.825); catalogued as rs564869863, COSV63679506; ClinVar: uncertain significance; called by muse, mutect2
- SCARA5 | c.442C>T p.R148W | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as rs756374530, COSV57276967; called by muse, mutect2
- SLC2A14 | c.313G>A p.V105I | Missense Mutation (SNP) | VAF 25/256 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.11); catalogued as COSV61587737; called by muse, mutect2
- TMEM30B | c.901C>T p.L301F | Missense Mutation (SNP) | VAF 44/445 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.27); catalogued as COSV63133081; called by muse, mutect2
- TNS1 | c.4909G>C p.V1637L | Missense Mutation (SNP) | VAF 25/314 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.153); catalogued as COSV50761385; called by muse, mutect2
- AGAP6 | c.478A>G p.T160A (on ENST00000374056 / NM_001365867.1; = p.T183A on NM_001077665.2) | Missense Mutation (SNP) | VAF 50/806 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2
- BCL7A | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 42/384 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- CKAP5 | c.2628T>G p.I876M | Missense Mutation (SNP) | VAF 18/332 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- COG6 | c.237T>G p.I79M | Missense Mutation (SNP) | VAF 41/393 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- COL11A1 | c.2503-2A>C p.X835_splice | Splice Site (SNP) | VAF 27/345 reads (8%) | called by muse, mutect2
- CUL4B | c.1249G>T p.V417F | Missense Mutation (SNP) | VAF 38/503 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- GSAP | c.1887A>C p.K629N | Missense Mutation (SNP) | VAF 18/209 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.106); called by muse, mutect2
- HGF | c.1545T>G p.N515K | Missense Mutation (SNP) | VAF 25/440 reads (6%) | SIFT tolerated (0.87); PolyPhen possibly damaging (0.905); called by muse, mutect2
- KCNA6 | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 49/431 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- LRP1 | c.365A>G p.H122R | Missense Mutation (SNP) | VAF 26/314 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.026); called by muse, mutect2
- NEXMIF | c.4490C>A p.T1497K | Missense Mutation (SNP) | VAF 34/322 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.01); called by muse, mutect2
- OR4K5 | c.271A>C p.T91P | Missense Mutation (SNP) | VAF 52/1185 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2
- PGM5 | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 49/572 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.75); called by muse, mutect2
- PHF24 | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 34/405 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2
- PRODH2 | c.1426G>T p.G476W (on ENST00000301175; = p.G400W on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/405 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PYHIN1 | c.554C>A p.A185D | Missense Mutation (SNP) | VAF 56/188 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); called by muse, varscan2
- PYURF | c.278A>T p.N93I | Missense Mutation (SNP) | VAF 13/254 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RXYLT1 | c.1223T>A p.I408N | Missense Mutation (SNP) | VAF 34/279 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- SCN3A | c.4882A>G p.I1628V | Missense Mutation (SNP) | VAF 64/704 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); called by muse, mutect2
- SPTLC2 | c.1675G>A p.E559K | Missense Mutation (SNP) | VAF 74/744 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- TBR1 | c.1556C>T p.A519V | Missense Mutation (SNP) | VAF 36/263 reads (14%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TMEM200C | c.1090C>T p.R364C | Missense Mutation (SNP) | VAF 29/353 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); called by muse, mutect2
- TRDJ2 | c.22T>C p.F8L | Missense Mutation (SNP) | VAF 46/447 reads (10%) | called by muse, mutect2, varscan2
- TSSK1B | c.124A>T p.I42F | Missense Mutation (SNP) | VAF 38/440 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- VAV3 | c.2321G>C p.G774A | Missense Mutation (SNP) | VAF 22/281 reads (8%) | SIFT tolerated (0.78); PolyPhen benign (0.019); called by muse, mutect2
- ZNF182 | c.859G>T p.E287* | Nonsense Mutation (SNP) | VAF 17/177 reads (10%) | called by muse, mutect2
- CACNA1E | c.4335G>A p.A1445= | Silent (SNP) | VAF 31/263 reads (12%) | catalogued as rs779279181; called by muse, mutect2
- GGA2 | c.774C>A p.A258= | Silent (SNP) | VAF 39/369 reads (11%) | called by muse, mutect2, varscan2
- IGFN1 | c.2301T>A p.P767= (on ENST00000295591 / NM_001367841.1; = p.P3224= on NM_001164586.2) | Silent (SNP) | VAF 44/555 reads (8%) | called by muse, mutect2
- KLKB1 | c.1452C>T p.I484= | Silent (SNP) | VAF 34/315 reads (11%) | catalogued as rs1340485490, COSV52994761; called by muse, mutect2, varscan2
- LRRTM1 | c.615C>T p.F205= | Silent (SNP) | VAF 26/456 reads (6%) | catalogued as COSV54437951; called by muse, mutect2
- MPO | c.1827G>A p.P609= | Silent (SNP) | VAF 42/398 reads (11%) | catalogued as rs781536912, COSV51859729; called by muse, mutect2
- NELL2 | c.1980C>T p.C660= | Silent (SNP) | VAF 40/407 reads (10%) | called by muse, mutect2, varscan2
- PCDHA7 | c.1671C>T p.D557= | Silent (SNP) | VAF 118/710 reads (17%) | catalogued as COSV65343247; called by muse, mutect2, varscan2
- PCP4 | c.129G>A p.A43= | Silent (SNP) | VAF 12/192 reads (6%) | catalogued as rs769109934, COSV60786391, COSV60788080; called by muse, mutect2
- POM121L2 | c.129C>T p.F43= | Silent (SNP) | VAF 5/58 reads (9%) | called by muse, mutect2
- PRDM12 | c.507C>T p.N169= | Silent (SNP) | VAF 34/418 reads (8%) | catalogued as rs369430134; called by muse, mutect2
- SGSM3 | c.879G>C p.L293= | Silent (SNP) | VAF 28/366 reads (8%) | catalogued as rs917899331; called by muse, mutect2
- ZMYND11 | c.1026T>C p.G342= | Silent (SNP) | VAF 78/746 reads (10%) | called by mutect2, varscan2
- AC016705.2 | n.154C>A | RNA (SNP) | VAF 29/385 reads (8%) | catalogued as rs755386647; called by muse, mutect2
- AP002008.2 | n.1464C>A | RNA (SNP) | VAF 13/114 reads (11%) | called by muse, varscan2
- CICP28 | chr7:56812094 A>T | 3'Flank (SNP) | VAF 43/339 reads (13%) | called by muse, mutect2, varscan2
- COL24A1 | c.-5T>C | 5'UTR (SNP) | VAF 14/153 reads (9%) | catalogued as rs1162021081; called by muse, mutect2
- DPPA3P2 | n.324C>T | RNA (SNP) | VAF 55/629 reads (9%) | catalogued as rs758258053; called by muse, mutect2
- ECD | c.1128-1711G>A | Intron (SNP) | VAF 5/48 reads (10%) | called by muse, mutect2
- EML4 | chr2:42333828 C>A | 3'Flank (SNP) | VAF 16/210 reads (8%) | called by muse, mutect2
- FILIP1L | chr3:99830603 G>A | 3'Flank (SNP) | VAF 18/187 reads (10%) | called by muse, mutect2
- FOXN3 | c.543+10324C>A | Intron (SNP) | VAF 45/451 reads (10%) | catalogued as COSV54315011; called by muse, mutect2, varscan2
- HBE1 | c.-267+102318A>G | Intron (SNP) | VAF 31/474 reads (7%) | called by muse, mutect2
- HMBS | c.160+46C>T | Intron (SNP) | VAF 50/725 reads (7%) | called by muse, mutect2
- KRT81 | c.-3A>T | 5'UTR (SNP) | VAF 48/633 reads (8%) | called by muse, mutect2
- NOC2LP2 | n.950T>A | RNA (SNP) | VAF 69/846 reads (8%) | called by muse, mutect2
- NXF5 | n.345A>T | RNA (SNP) | VAF 50/278 reads (18%) | called by muse, mutect2, varscan2
- PCDHB6 | chr5:141156188 G>A | 3'Flank (SNP) | VAF 26/265 reads (10%) | called by muse, mutect2, varscan2
- TBRG4 | c.-66C>T | 5'UTR (SNP) | VAF 34/372 reads (9%) | catalogued as rs1013396252, COSV99345789; called by muse, mutect2
- TMEM135 | c.*7180G>T | 3'UTR (SNP) | VAF 34/422 reads (8%) | called by muse, mutect2
- ZIC4 | c.-16+955G>A | Intron (SNP) | VAF 19/244 reads (8%) | called by muse, mutect2
- ZNF740 | c.-43dup | 5'UTR (INS) | VAF 14/142 reads (10%) | called by mutect2, varscan2
